Somatic mutation profile of tumor specimen C3L-00918-01 (aliquot CPT0063790006) from CPTAC case C3L-00918, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 69.0 years (25,195 days).
Specimen C3L-00918-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 610d7d7d-c09e-4dd0-b9ec-25fcd0846963.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00918-31 (Blood Derived Normal), aliquot CPT0065320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8d8febb-0267-4f69-8132-70ea4301253b

The open-access MAF lists 482 somatic variants for this specimen: 340 protein-altering or splice-affecting, 88 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 88, Frame Shift Del 74, Intron 36, Frame Shift Ins 19, Nonsense Mutation 18, 3'UTR 6, Splice Region 6, 5'UTR 4, 3'Flank 3, Splice Site 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.1865del p.P622Lfs*144 | Frame Shift Del (DEL) | VAF 73/592 reads (12%) | catalogued as rs72651620, CD063487; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HSPG2 | c.10894C>T p.R3632* | Nonsense Mutation (SNP) | VAF 54/458 reads (12%) | catalogued as rs762281715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 96/360 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LTBP4 | c.4240C>T p.R1414* (on ENST00000308370 / NM_001042544.1; = p.R1377* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as rs1382026467, CM130163; ClinVar: pathogenic; called by muse, mutect2
- NFE2L2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 85/418 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960000, COSV67960068, COSV67960466; called by muse, mutect2, varscan2
- NPHS1 | c.3250del p.V1084Sfs*59 | Frame Shift Del (DEL) | VAF 65/581 reads (11%) | catalogued as rs386833935, CD994100; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 106/590 reads (18%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 35/359 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- STAR | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 74/677 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs139081695, CM114710; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.103del p.Q35Nfs*5 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV61363906; called by mutect2, pindel, varscan2
- ACTL6A | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs886766022; called by muse, mutect2, varscan2
- ADAMTS13 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1027868756; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755153311; called by muse, mutect2, varscan2
- ADCY1 | c.3264_3265insT p.V1089Cfs*97 | Frame Shift Ins (INS) | VAF 53/396 reads (13%) | catalogued as COSV99812966; called by mutect2, pindel, varscan2
- ADGRF4 | c.506del p.N169Ifs*15 | Frame Shift Del (DEL) | VAF 31/264 reads (12%) | catalogued as rs1178459999; called by mutect2, pindel
- ADGRV1 | c.7078C>T p.R2360C | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs369782677; called by muse, mutect2, varscan2
- AMER1 | c.785T>G p.M262R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57659376; called by muse, mutect2, varscan2
- ANK3 | c.12836C>T p.T4279I (on ENST00000280772 / NM_001320874.2; = p.T903I on NM_001149.3) | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs914801576; called by muse, mutect2, varscan2
- ASPH | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs373501060; called by muse, mutect2
- ATAD2 | c.3359C>T p.P1120L | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54884965; called by muse, mutect2
- AUTS2 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.337); catalogued as COSV100715360; called by muse, varscan2
- BMP1 | c.2713G>A p.V905M | Missense Mutation (SNP) | VAF 67/561 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs774390712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 20/375 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101122076; called by muse, mutect2
- BOLA1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as rs782038690; called by muse, mutect2, varscan2
- BSN | c.10912C>T p.R3638C | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs200331614; called by muse, mutect2, varscan2
- C4orf54 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs1328014162, COSV72767113; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 54/235 reads (23%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as COSV61714509; called by mutect2, pindel
- CACNA1H | c.5654C>T p.A1885V | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs374079245, COSV52355914; called by muse, mutect2, varscan2
- CACNA2D1 | c.2018C>T p.S673L (on ENST00000356253 / NM_001366867.1; = p.S661L on NM_000722.4) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs779137994, COSV62373938; called by muse, mutect2, varscan2
- CC2D2A | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs145945939; called by muse, mutect2, varscan2
- CCDC116 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs139995363; called by muse, mutect2, varscan2
- CD2AP | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); catalogued as rs1437681570, COSV63763230; called by muse, mutect2
- CDH3 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.462); catalogued as COSV50561866; called by muse, mutect2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs769310263; called by mutect2, pindel
- CGN | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs575710911, COSV104376576; called by muse, mutect2
- CHPF2 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 59/236 reads (25%) | catalogued as rs748127148; called by muse, mutect2, varscan2
- CHTF18 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1411972877; called by muse, mutect2, varscan2
- CNTN4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1195160321, COSV68568827; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 54/379 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as rs1219292587; called by muse, mutect2, varscan2
- CTSK | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 91/375 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55011286; called by muse, mutect2, varscan2
- CUBN | c.4045C>T p.R1349C | Missense Mutation (SNP) | VAF 63/602 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs757977392, COSV64712807; called by muse, mutect2, varscan2
- DCAF12L2 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100758441; called by muse, mutect2
- DNMT3B | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs777301633; called by muse, mutect2
- DUSP5 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs781499980, COSV63646979; called by muse, mutect2, varscan2
- DYNC1H1 | c.9656G>A p.R3219H | Missense Mutation (SNP) | VAF 98/832 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1460582982; called by muse, mutect2, varscan2
- ELMO1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs767179282; called by muse, mutect2, varscan2
- EPS8L3 | c.984C>A p.C328* | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | catalogued as COSV62610538; called by muse, varscan2
- ETV5 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 123/622 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs749844496, COSV60502158; called by muse, mutect2, varscan2
- FAM118A | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs768565583, COSV53418332; called by muse, mutect2, varscan2
- FAM171A1 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 31/230 reads (13%) | catalogued as COSV65315730; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAT3 | c.4025C>T p.T1342M | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565456861, COSV53072072; called by muse, mutect2
- FBXL17 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs946355528, COSV62856168; called by muse, mutect2
- FHOD1 | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1206941866, COSV50764223; called by muse, mutect2
- GALNT15 | c.409del p.A137Lfs*13 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | catalogued as COSV60215076, COSV60216772; called by mutect2, pindel, varscan2
- GPR158 | c.3108G>A p.M1036I | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV66275282, COSV66284720; called by muse, mutect2, varscan2
- GRIP2 | c.1573C>T p.R525* (on ENST00000619221; = p.R428* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs1205562054, COSV99817655; called by muse, mutect2
- GRK2 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1353635469; called by muse, mutect2
- HCN4 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.149); catalogued as rs745617328, COSV56086610; called by muse, mutect2, varscan2
- HLA-G | c.617C>G p.A206G | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV64406376; called by muse, mutect2
- HNRNPUL1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54567672; called by muse, mutect2, varscan2
- INPP5D | c.1874G>T p.R625M (on ENST00000445964 / NM_001017915.3; = p.R624M on NM_005541.5) | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100856740, COSV64037106; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 29/131 reads (22%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSC | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs1018032720; called by muse, mutect2, varscan2
- INSL6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs971310807, COSV67562571, COSV67563158; called by muse, mutect2, varscan2
- ITIH6 | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54486999; called by muse, mutect2, varscan2
- KANSL1L | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1407345263; called by muse, mutect2, varscan2
- KBTBD13 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 108/964 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV71351477; called by muse, mutect2, varscan2
- KCNB2 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73051019; called by muse, mutect2, varscan2
- KIF26A | c.4085del p.P1362Rfs*24 | Frame Shift Del (DEL) | VAF 21/131 reads (16%) | catalogued as rs776136395; called by mutect2, pindel, varscan2
- KIF26B | c.4651G>A p.D1551N | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1396936715; called by muse, mutect2, varscan2
- KLK4 | c.627del p.L211* | Frame Shift Del (DEL) | VAF 76/643 reads (12%) | catalogued as rs1410607661; called by mutect2, pindel
- LAPTM4B | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs760702744; called by muse, mutect2, varscan2
- LCOR | c.2151del p.M718* | Frame Shift Del (DEL) | VAF 17/206 reads (8%) | catalogued as rs1564645983; called by mutect2, pindel
- LILRA6 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1335374079; called by muse, mutect2, varscan2
- LRFN3 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs762327691; called by muse, mutect2, varscan2
- LRP2BP | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs765686066, COSV60749431; called by muse, mutect2, varscan2
- MAP2K7 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1445100216, COSV67608063; called by muse, varscan2
- MAP2K7 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67607651; called by muse, varscan2
- MAP3K21 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486052733, COSV64044637; called by muse, mutect2
- MAPK8IP3 | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1180762344; called by muse, mutect2
- MAST4 | c.4103G>A p.R1368Q (on ENST00000403625 / NM_001164664.2; = p.R1179Q on NM_015183.3) | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55123437; called by muse, mutect2
- MC1R | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 34/401 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201632257; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- MEIOC | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1375540728; called by muse, mutect2, varscan2
- MFSD8 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs200386040; called by muse, mutect2, varscan2
- MID2 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV53307513; called by muse, mutect2
- MUC4 | c.2500C>A p.P834T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.65); catalogued as rs955325139; called by muse, mutect2
- MYO1H | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as rs568424162, COSV100183621; called by muse, mutect2, varscan2
- NAT8L | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs771204097; called by muse, mutect2, varscan2
- NBAS | c.6467G>A p.R2156H | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769562325, COSV55728484, COSV99870643; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEU4 | c.680C>T p.A227V (on ENST00000391969 / NM_001167602.3; = p.A239V on NM_080741.4) | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as rs374258246; called by muse, mutect2, varscan2
- NEXMIF | c.3931C>T p.R1311W | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145673087, COSV99281061; called by muse, mutect2, varscan2
- NMUR1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59403782; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs753934412; called by mutect2, pindel
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NPHS1 | c.3554del p.P1185Rfs*52 | Frame Shift Del (DEL) | VAF 69/576 reads (12%) | catalogued as COSV100800437, COSV62287222; called by mutect2, pindel, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | catalogued as rs776154715; called by mutect2, varscan2
- NRIP1 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1338383258; called by muse, mutect2
- NRK | c.2344del p.I782Lfs*66 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | catalogued as COSV54591328; called by mutect2, pindel
- NRXN1 | c.3965T>C p.M1322T | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV60485589; called by muse, mutect2, varscan2
- NYAP2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1361526299, COSV56007357; called by muse, mutect2, varscan2
- OLFML3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs779305718; called by muse, mutect2, varscan2
- PANK4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as rs377690916; called by muse, mutect2
- PCDHA5 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as rs191497891; called by muse, mutect2, varscan2
- PIK3C2G | c.4011C>T p.N1337= (on ENST00000676171; = p.N1296= on NM_004570.5) | Splice Region (SNP) | VAF 14/99 reads (14%) | catalogued as rs570833233; called by muse, mutect2
- PIK3C2G | c.4178A>G p.N1393S (on ENST00000676171; = p.N1352S on NM_004570.5) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs764099520; called by muse, mutect2, varscan2
- PITRM1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs760564399; called by muse, mutect2
- PLXNA1 | c.3629C>T p.A1210V | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs758654359; called by muse, mutect2, varscan2
- POLRMT | c.2327G>T p.R776L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52112115; called by mutect2, varscan2
- PPP2R2A | c.844T>C p.S282P | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60096363, COSV60097101; called by muse, mutect2, varscan2
- PRUNE1 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs373152187; called by muse, mutect2, varscan2
- RBBP6 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1012879002, COSV60502958; called by muse, mutect2
- RBM6 | c.293dup p.D99Rfs*6 | Frame Shift Ins (INS) | VAF 36/298 reads (12%) | catalogued as rs764709206; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as COSV56484832; called by mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 22/174 reads (13%) | catalogued as COSV65365594; called by mutect2, pindel
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs759247453; called by mutect2, varscan2
- RGPD3 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 91/907 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201811240; called by mutect2, varscan2
- RGPD4 | c.4803del p.K1601Nfs*69 | Frame Shift Del (DEL) | VAF 34/287 reads (12%) | catalogued as rs1558816973; called by mutect2, varscan2
- RGS12 | c.4159A>G p.I1387V (on ENST00000336727; = p.I739V on NM_198227.2) | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs528267044; called by muse, mutect2
- RMDN2 | c.976del p.M326Wfs*39 (on ENST00000354545 / NM_001322212.2; = p.M504Wfs*39 on NM_144713.5) | Frame Shift Del (DEL) | VAF 33/226 reads (15%) | catalogued as rs770517879; called by mutect2, pindel, varscan2
- RNF151 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1001374265, COSV58400483; called by muse, mutect2, varscan2
- RNF38 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1451832103; called by muse, mutect2, varscan2
- RNF44 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772649637; called by muse, mutect2, varscan2
- RXFP2 | c.918T>A p.N306K | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53635883; called by muse, mutect2, varscan2
- RYR2 | c.3932C>T p.A1311V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs757471928, COSV63661231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.5029G>A p.A1677T (on ENST00000333535 / NM_198056.3; = p.A1676T on NM_000335.5) | Missense Mutation (SNP) | VAF 56/523 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV61130730; called by muse, mutect2, varscan2
- SF3B4 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as rs915419686; called by muse, mutect2
- SHROOM2 | c.2403dup p.E802* | Frame Shift Ins (INS) | VAF 28/202 reads (14%) | catalogued as rs1404994439; called by mutect2, pindel
- SLC4A3 | c.300dup p.T101Hfs*36 | Frame Shift Ins (INS) | VAF 17/138 reads (12%) | catalogued as rs1303003769; called by mutect2, pindel
- SMIM13 | c.104dup p.L35Ffs*22 | Frame Shift Ins (INS) | VAF 30/254 reads (12%) | catalogued as rs906089964; called by mutect2, varscan2
- SOSTDC1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770948074, COSV61049264; called by muse, mutect2, varscan2
- SPACA1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs200613021; called by muse, mutect2, varscan2
- SPAG7 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1440069842; called by muse, mutect2
- SPATC1 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139671299; called by muse, mutect2, varscan2
- SPTLC1 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 54/455 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs768829356, COSV52765425, COSV99364747; called by muse, mutect2, varscan2
- STAB1 | c.4015del p.V1339Cfs*252 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs761841917, COSV100402435; called by mutect2, pindel, varscan2
- STRN4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1439708882; called by muse, mutect2
- SZT2 | c.802A>G p.S268G | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.058); catalogued as rs1051327530; called by muse, mutect2, varscan2
- TARBP1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.244); catalogued as rs375612449; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBX3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 108/951 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs768160499, COSV57471248, COSV99983739; called by muse, mutect2, varscan2
- TLE4 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1215372546, COSV99511415; called by muse, mutect2, varscan2
- TRPM1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs750109963, CM158233, COSV56640995; called by muse, mutect2
- UHRF2 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs979660065; called by muse, mutect2, varscan2
- USP17L7 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 64/406 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540951599; called by muse, varscan2
- VPS9D1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758796911, COSV57071047; called by muse, mutect2, varscan2
- ZC3H13 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as rs1436777526, COSV99667911; called by muse, mutect2, varscan2
- ZNF468 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.583); catalogued as rs772403344, COSV54695472; called by muse, mutect2
- ZNF615 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762696316; called by muse, mutect2, varscan2
- ZNF800 | c.1322del p.K441Rfs*61 | Frame Shift Del (DEL) | VAF 12/136 reads (9%) | catalogued as rs1346638445; called by mutect2, pindel
- ABCG5 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ADAMTSL2 | c.267del p.C90Afs*127 | Frame Shift Del (DEL) | VAF 60/553 reads (11%) | called by mutect2, pindel
- ADGRA3 | c.2814A>G p.I938M | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADGRF3 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ADNP2 | c.1288C>A p.L430M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- AGPAT3 | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 92/624 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ALPK1 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- APLP1 | c.1591C>T p.Q531* (on ENST00000221891 / NM_001024807.3; = p.Q530* on NM_005166.4) | Nonsense Mutation (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2
- AQR | c.910A>T p.M304L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARAP2 | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- ARHGAP35 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 60/283 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.1499A>C p.Q500P | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- ARID5B | c.1338_1371del p.H446Qfs*22 | Frame Shift Del (DEL) | VAF 42/237 reads (18%) | called by mutect2, pindel
- ARMH2 | c.114del p.F38Lfs*28 | Frame Shift Del (DEL) | VAF 36/314 reads (11%) | called by mutect2, pindel
- ASB13 | c.749dup p.L250Ffs*24 | Frame Shift Ins (INS) | VAF 25/335 reads (7%) | called by mutect2, pindel
- ATF7IP | c.2650G>C p.A884P | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 87/634 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 38/238 reads (16%) | called by mutect2, varscan2
- BRD2 | c.169dup p.T57Nfs*71 | Frame Shift Ins (INS) | VAF 98/402 reads (24%) | called by mutect2, pindel, varscan2
- BTNL9 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- BUB1B | c.2189T>C p.L730P | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- C16orf72 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CACNA1B | c.6730del p.L2244Sfs*57 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.4766C>A p.P1589H | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CDCA2 | c.2079del p.A694Qfs*24 | Frame Shift Del (DEL) | VAF 20/186 reads (11%) | called by mutect2, pindel
- CDHR2 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.152); called by muse, mutect2
- CDK4 | c.817C>T p.L273= | Splice Region (SNP) | VAF 27/289 reads (9%) | called by muse, mutect2
- CEP170 | c.2818A>G p.T940A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CHD6 | c.781del p.E261Kfs*98 | Frame Shift Del (DEL) | VAF 31/335 reads (9%) | called by mutect2, pindel
- CHERP | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- CLEC18C | c.125-3dup | Splice Region (INS) | VAF 22/234 reads (9%) | called by mutect2, pindel
- CLIC6 | c.1266del p.A423Pfs*10 | Frame Shift Del (DEL) | VAF 19/152 reads (13%) | called by mutect2, pindel, varscan2
- CNGA2 | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL2A1 | c.4060A>G p.N1354D | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2
- COL5A2 | c.3635del p.G1212Afs*61 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | called by mutect2, pindel, varscan2
- CR1 | c.4492T>C p.C1498R | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRACR2A | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- CRYBG1 | c.3386G>T p.R1129M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CSN2 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CUX1 | c.4351del p.R1451Afs*34 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, varscan2
- DBNL | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- DLL1 | c.1538del p.G513Vfs*24 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- DPP3 | c.1211T>G p.F404C | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DPP6 | c.1448G>T p.G483V (on ENST00000377770 / NM_001364500.2; = p.G421V on NM_001936.5) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DTNB | c.1671del p.T558Pfs*8 | Frame Shift Del (DEL) | VAF 28/231 reads (12%) | called by mutect2, pindel, varscan2
- DUOXA1 | c.555-1G>T p.X185_splice | Splice Site (SNP) | VAF 14/394 reads (4%) | called by muse, mutect2
- EEF1E1 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/135 reads (16%) | called by mutect2, pindel, varscan2
- ENTPD2 | c.611del p.G204Vfs*171 | Frame Shift Del (DEL) | VAF 64/521 reads (12%) | called by mutect2, pindel, varscan2
- EP300 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- EPHB1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHX2 | c.548del p.L183Wfs*8 | Frame Shift Del (DEL) | VAF 20/164 reads (12%) | called by mutect2, varscan2
- FAM120A | c.2897dup p.R967Pfs*16 | Frame Shift Ins (INS) | VAF 47/388 reads (12%) | called by mutect2, pindel, varscan2
- FAM181B | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM214A | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83H | c.1436dup p.R480Pfs*9 | Frame Shift Ins (INS) | VAF 116/860 reads (13%) | called by mutect2, pindel
- FARP1 | c.2274+5G>T | Splice Region (SNP) | VAF 44/363 reads (12%) | called by muse, mutect2, varscan2
- FN1 | c.4859_4862del p.E1620Vfs*9 | Frame Shift Del (DEL) | VAF 76/645 reads (12%) | called by mutect2, pindel
- GDF6 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GEM | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA1 | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 28/655 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2
- GRIN2D | c.898del p.L300Cfs*27 | Frame Shift Del (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- GYPC | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- H4C8 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- HAUS7 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 137/509 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERC2P3 | n.1577C>T | Splice Region (SNP) | VAF 113/222 reads (51%) | called by muse, mutect2, varscan2
- HES6 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- HHIP | c.989del p.N330Ifs*7 | Frame Shift Del (DEL) | VAF 37/282 reads (13%) | called by mutect2, pindel, varscan2
- HIKESHI | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- HOXC6 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA12B | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.274_285del p.D92_M95del | In Frame Del (DEL) | VAF 46/632 reads (7%) | called by mutect2, pindel
- IGSF1 | c.2407del p.H803Tfs*4 | Frame Shift Del (DEL) | VAF 34/372 reads (9%) | called by mutect2, pindel
- INF2 | c.1587del p.V530Wfs*28 | Frame Shift Del (DEL) | VAF 36/241 reads (15%) | called by mutect2, varscan2
- INPP5F | c.2023del p.I675Lfs*3 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- JMJD7-PLA2G4B | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- KCNH5 | c.1188dup p.G397Wfs*87 | Frame Shift Ins (INS) | VAF 61/438 reads (14%) | called by mutect2, pindel, varscan2
- KCNK12 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNQ3 | c.359dup p.W121Lfs*29 | Frame Shift Ins (INS) | VAF 22/169 reads (13%) | called by mutect2, pindel, varscan2
- KDM8 | c.766A>G p.N256D | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIAA0930 | c.139del p.R47Gfs*60 (on ENST00000336156 / NM_001009880.2; = p.R52Gfs*60 on NM_015264.2) | Frame Shift Del (DEL) | VAF 54/449 reads (12%) | called by mutect2, varscan2
- KIDINS220 | c.2303G>T p.R768M | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL21 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, varscan2
- KLK8 | c.743A>C p.Y248S | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KPTN | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LIPK | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LRIG3 | c.778del p.W260Gfs*3 | Frame Shift Del (DEL) | VAF 17/164 reads (10%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- MAGI3 | c.4072del p.I1358Sfs*13 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by mutect2, pindel
- MARCKSL1 | c.246del p.K83Rfs*18 | Frame Shift Del (DEL) | VAF 19/157 reads (12%) | called by mutect2, pindel
- MBOAT7 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- METTL16 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKNK2 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2
- MNT | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2657dup p.Q887Afs*17 | Frame Shift Ins (INS) | VAF 26/195 reads (13%) | called by mutect2, pindel, varscan2
- MPPED2 | c.815C>A p.T272K | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.538); called by muse, mutect2
- MROH6 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2
- MTCL1 | c.2593del p.D865Tfs*15 (on ENST00000306329 / NM_001378206.1; = p.D505Tfs*15 on NM_015210.4) | Frame Shift Del (DEL) | VAF 8/108 reads (7%) | called by mutect2, pindel
- MTHFD2 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.12); called by muse, mutect2
- MYBPH | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MYRFL | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYT1L | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- NACC2 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 62/610 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- NCAPD3 | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCDN | c.418dup p.R140Pfs*14 | Frame Shift Ins (INS) | VAF 45/340 reads (13%) | called by mutect2*, pindel
- NOP14 | c.364A>C p.N122H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRIP1 | c.1547del p.N516Tfs*11 | Frame Shift Del (DEL) | VAF 18/258 reads (7%) | called by mutect2, pindel
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 72/628 reads (11%) | called by mutect2, pindel, varscan2
- OR14A16 | c.926del p.K309Sfs*? | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- OR4C12 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OR5A2 | c.221_222del p.Y74Cfs*7 | Frame Shift Del (DEL) | VAF 35/248 reads (14%) | called by mutect2, pindel, varscan2
- OR7A17 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PBX3 | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCDHB6 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 124/1128 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, varscan2
- PCDHGB3 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PDLIM3 | c.376C>T p.L126F (on ENST00000284770 / NM_001257963.1; = p.L293F on NM_014476.6) | Missense Mutation (SNP) | VAF 127/476 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGD | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2, varscan2
- PHYHIP | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.3620T>A p.L1207Q | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- PLPPR5 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2
- PLRG1 | c.1053T>A p.D351E | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNB2 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLXNB3 | c.5364G>T p.Q1788H | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA4 | c.677del p.P226Qfs*35 | Frame Shift Del (DEL) | VAF 28/206 reads (14%) | called by mutect2, pindel, varscan2
- PNPLA7 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- POLR3A | c.3862A>G p.M1288V | Missense Mutation (SNP) | VAF 90/863 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PPFIBP1 | c.1963T>G p.W655G (on ENST00000318304 / NM_177444.3; = p.W649G on NM_003622.4) | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM16 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2
- PTEN | c.882dup p.L295Sfs*3 | Frame Shift Ins (INS) | VAF 52/215 reads (24%) | called by mutect2, pindel, varscan2
- PTPRCAP | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- RAB20 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RAB39A | c.542del p.K181Rfs*29 | Frame Shift Del (DEL) | VAF 26/203 reads (13%) | called by mutect2, pindel
- RANBP3 | c.26A>T p.K9M | Missense Mutation (SNP) | VAF 16/331 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBP3 | c.2360G>A p.G787D | Missense Mutation (SNP) | VAF 19/572 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RGS1 | c.142A>G p.M48V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF126 | c.576+6G>A | Splice Region (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- RNF2 | c.670A>G p.S224G | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KA6 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- RYR2 | c.4684-1G>A p.X1562_splice | Splice Site (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- S100A13 | c.244dup p.E82Gfs*23 | Frame Shift Ins (INS) | VAF 27/201 reads (13%) | called by mutect2, pindel, varscan2
- SBF2 | c.4091C>T p.T1364I | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SBNO2 | c.3296del p.G1099Afs*36 | Frame Shift Del (DEL) | VAF 37/400 reads (9%) | called by mutect2, pindel
- SFSWAP | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3TC1 | c.3796G>A p.A1266T | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.3464T>C p.I1155T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SLC1A1 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 55/571 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC25A31 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 42/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC34A2 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 23/594 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- SLC39A10 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- SLC7A3 | c.212T>G p.L71W | Missense Mutation (SNP) | VAF 100/405 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC8A3 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 17/298 reads (6%) | called by muse, mutect2
- SLIT3 | c.2767A>G p.S923G | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLITRK1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, varscan2
- SPRED2 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSC4D | c.497dup p.T167Nfs*8 | Frame Shift Ins (INS) | VAF 31/256 reads (12%) | called by mutect2, pindel, varscan2
- SSRP1 | c.1988_1989del p.K663Rfs*5 | Frame Shift Del (DEL) | VAF 29/257 reads (11%) | called by mutect2, pindel, varscan2
- STN1 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT20HL2 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- SYT8 | c.1059del p.Q354Sfs*? | Frame Shift Del (DEL) | VAF 10/117 reads (9%) | called by mutect2, pindel
- TENM3 | c.6493A>G p.S2165G | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.1569del p.S524Pfs*85 | Frame Shift Del (DEL) | VAF 37/231 reads (16%) | called by mutect2, pindel, varscan2
- TM6SF1 | c.1007del p.L336* | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by mutect2, varscan2
- TMEM41B | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM92 | c.413del p.P138Lfs*86 | Frame Shift Del (DEL) | VAF 34/296 reads (11%) | called by mutect2, pindel
- TMOD2 | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TRIM27 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TRIM37 | c.474del p.S159Afs*2 | Frame Shift Del (DEL) | VAF 68/278 reads (24%) | called by mutect2, pindel, varscan2
- TRMT2A | c.1182C>A p.H394Q | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBR5 | c.5150C>A p.A1717D | Missense Mutation (SNP) | VAF 56/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UGT2B11 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- UNC5B | c.538del p.V180Cfs*66 | Frame Shift Del (DEL) | VAF 34/216 reads (16%) | called by mutect2, pindel, varscan2
- USP5 | c.2483+2T>C p.X828_splice (on ENST00000229268 / NM_001098536.2; = p.X805_splice on NM_003481.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- VANGL2 | c.1162del p.R388Gfs*45 | Frame Shift Del (DEL) | VAF 73/487 reads (15%) | called by mutect2, pindel, varscan2
- WDR81 | c.152del p.G51Afs*7 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- XKR6 | c.1562del p.P521Lfs*27 | Frame Shift Del (DEL) | VAF 25/172 reads (15%) | called by mutect2, pindel, varscan2
- YRDC | c.537dup p.M180Yfs*9 | Frame Shift Ins (INS) | VAF 32/316 reads (10%) | called by mutect2, pindel
- ZC3H12B | c.2071del p.Q691Sfs*7 | Frame Shift Del (DEL) | VAF 12/123 reads (10%) | called by mutect2, pindel
- ZC3H13 | c.3104dup p.I1036Yfs*4 | Frame Shift Ins (INS) | VAF 21/173 reads (12%) | called by mutect2, pindel, varscan2
- ZNF10 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF112 | c.2094_2095del p.C698Wfs*2 (on ENST00000337401 / NM_001083335.2; = p.C692Wfs*2 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/230 reads (14%) | called by pindel, varscan2
- ZNF132 | c.1009C>A p.H337N | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF44 | c.766dup p.W256Lfs*9 (on ENST00000356109 / NM_001164276.2; = p.W208Lfs*9 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 26/228 reads (11%) | called by mutect2, varscan2
- ZNF549 | c.1291del p.R431Dfs*206 (on ENST00000376233 / NM_001199295.2; = p.R418Dfs*206 on NM_153263.2) | Frame Shift Del (DEL) | VAF 28/231 reads (12%) | called by mutect2, pindel, varscan2
- ZNF638 | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- ZNF773 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ZNF777 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ADAMTS7 | c.4773G>A p.R1591= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2007A>T p.P669= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, varscan2
- AHNAK2 | c.8853G>A p.P2951= | Silent (SNP) | VAF 76/650 reads (12%) | catalogued as rs548525077, COSV60910017; called by muse, mutect2, varscan2
- AK5 | c.1665C>T p.C555= (on ENST00000354567 / NM_174858.3; = p.C529= on NM_012093.4) | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV60976928; called by muse, mutect2, varscan2
- ANLN | c.927T>C p.C309= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as COSV56077323; called by muse, mutect2, varscan2
- ARHGEF37 | c.843G>C p.L281= | Silent (SNP) | VAF 19/224 reads (8%) | called by muse, mutect2
- BHMG1 | c.1050C>T p.V350= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as rs1270081535; called by muse, mutect2, varscan2
- BRPF1 | c.3633C>T p.S1211= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs748755249, COSV57353170; called by muse, mutect2
- CAP2 | c.405C>T p.A135= | Silent (SNP) | VAF 32/245 reads (13%) | catalogued as rs146710056; called by muse, mutect2, varscan2
- CD53 | c.153G>A p.T51= | Silent (SNP) | VAF 63/490 reads (13%) | catalogued as rs745562046, COSV99602426; called by muse, mutect2, varscan2
- CEP152 | c.4176T>C p.I1392= (on ENST00000380950 / NM_001194998.2; = p.I1336= on NM_014985.4) | Silent (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- CHD3 | c.3435G>A p.L1145= | Silent (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- COG1 | c.1230G>A p.P410= | Silent (SNP) | VAF 98/771 reads (13%) | catalogued as rs148502827; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CSMD1 | c.7743C>T p.Y2581= (on ENST00000520002; = p.Y2580= on NM_033225.6) | Silent (SNP) | VAF 25/274 reads (9%) | catalogued as rs777432836, COSV59318061; called by muse, mutect2
- CXorf56 | c.102C>T p.C34= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- DDX39A | c.630G>A p.V210= | Silent (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- DHX37 | c.2148C>T p.N716= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs766329234; called by muse, mutect2
- DLG1 | c.1719A>G p.S573= | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as rs1312100430; called by muse, mutect2, varscan2
- DOCK6 | c.2898C>T p.D966= | Silent (SNP) | VAF 26/252 reads (10%) | catalogued as rs779109947; called by muse, mutect2, varscan2
- DOK7 | c.507T>C p.F169= | Silent (SNP) | VAF 26/622 reads (4%) | called by muse, mutect2
- EIF4G3 | c.201G>A p.A67= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs1267741197; called by muse, mutect2
- EPG5 | c.6837C>T p.N2279= | Silent (SNP) | VAF 59/543 reads (11%) | catalogued as rs377043340; called by muse, mutect2, varscan2
- EPHB1 | c.1542C>T p.Y514= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as rs781750969, COSV101213289; called by muse, mutect2, varscan2
- EPHB1 | c.2226T>C p.H742= | Silent (SNP) | VAF 46/478 reads (10%) | called by muse, mutect2
- FANCF | c.759C>T p.R253= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- FBXL7 | c.423C>T p.C141= | Silent (SNP) | VAF 22/409 reads (5%) | catalogued as rs980265395; called by muse, mutect2
- GDF1 | c.171G>A p.P57= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs968287517; called by muse, mutect2, varscan2
- GRK2 | c.1782C>T p.G594= | Silent (SNP) | VAF 33/288 reads (11%) | catalogued as rs777753774; called by muse, mutect2, varscan2
- HAUS5 | c.1842G>C p.L614= | Silent (SNP) | VAF 86/313 reads (27%) | called by muse, mutect2, varscan2
- HECTD4 | c.9969G>A p.S3323= | Silent (SNP) | VAF 38/239 reads (16%) | catalogued as rs367866576; called by muse, varscan2
- HS6ST2 | c.129C>T p.P43= | Silent (SNP) | VAF 40/307 reads (13%) | catalogued as rs771768484; called by muse, mutect2, varscan2
- IGSF21 | c.1401G>A p.T467= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs759862890, COSV52129288; called by muse, mutect2, varscan2
- IL13RA2 | c.747G>A p.E249= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV104387932; called by muse, mutect2, varscan2
- KIF14 | c.2706A>G p.V902= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV66261735; called by muse, mutect2
- KLHL30 | c.498A>G p.A166= | Silent (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
- KRI1 | c.681C>T p.Y227= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs1231172385; called by muse, mutect2, varscan2
- LAMB4 | c.1536T>C p.G512= | Silent (SNP) | VAF 40/259 reads (15%) | called by muse, varscan2
- LRWD1 | c.466C>T p.L156= | Silent (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- LTBP4 | c.4758G>A p.P1586= (on ENST00000308370 / NM_001042544.1; = p.P1549= on NM_003573.2) | Silent (SNP) | VAF 23/278 reads (8%) | catalogued as rs1039609333; called by muse, mutect2
- LTF | c.277C>T p.L93= | Silent (SNP) | VAF 56/274 reads (20%) | catalogued as rs1346588604; called by muse, mutect2, varscan2
- MCM3 | c.1113T>C p.T371= (on ENST00000229854 / NM_001366374.2; = p.T361= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 28/269 reads (10%) | catalogued as rs138846924; called by muse, mutect2, varscan2
- MRAP | c.120C>T p.I40= | Silent (SNP) | VAF 62/734 reads (8%) | catalogued as rs781283014; called by muse, mutect2
- MRPS30 | c.685T>C p.L229= | Silent (SNP) | VAF 19/201 reads (9%) | catalogued as COSV50181721; called by muse, mutect2
- MSH6 | c.3333T>C p.N1111= | Silent (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- MTHFSD | c.1134G>A p.R378= (on ENST00000360900 / NM_001159377.2; = p.R377= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1003577646; called by muse, mutect2, varscan2
- NECTIN1 | c.1182C>T p.H394= | Silent (SNP) | VAF 71/591 reads (12%) | catalogued as rs761931104, COSV50598241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEO1 | c.1653G>A p.S551= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as rs770185773, COSV99982268; called by muse, mutect2, varscan2
- NLE1 | c.1173C>A p.S391= | Silent (SNP) | VAF 66/575 reads (11%) | called by muse, mutect2, varscan2
- NOS1 | c.909A>G p.P303= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as rs1489697542; called by muse, mutect2, varscan2
- NPAP1 | c.529A>C p.R177= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- PAPPA | c.4479T>C p.P1493= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV100073161, COSV60281681; called by muse, mutect2, varscan2
- PCDHGA6 | c.276C>T p.R92= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as rs1179448303, COSV54021739; called by muse, varscan2
- PCDHGA6 | c.354C>A p.P118= | Silent (SNP) | VAF 28/214 reads (13%) | catalogued as rs549456032, COSV53911675; called by muse, varscan2
- PCLO | c.14757C>T p.A4919= | Silent (SNP) | VAF 85/648 reads (13%) | catalogued as rs746086173, COSV61651090; called by muse, mutect2, varscan2
- PDIA3 | c.816C>T p.N272= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as rs140476545; ClinVar: likely benign; called by muse, mutect2, varscan2
- PI16 | c.180C>T p.D60= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as rs1401842889; called by muse, mutect2
- PIK3C2B | c.2832T>C p.A944= | Silent (SNP) | VAF 13/347 reads (4%) | called by muse, mutect2
- PLXNB1 | c.978G>A p.L326= | Silent (SNP) | VAF 31/422 reads (7%) | catalogued as COSV56487759; called by muse, mutect2
- PLXNC1 | c.189C>T p.S63= | Silent (SNP) | VAF 28/248 reads (11%) | called by muse, mutect2, varscan2
- POLE | c.6795C>T p.Y2265= | Silent (SNP) | VAF 54/402 reads (13%) | catalogued as rs142222159; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- PRICKLE1 | c.1512T>C p.H504= | Silent (SNP) | VAF 60/530 reads (11%) | catalogued as rs769438599; called by muse, mutect2, varscan2
- PRKAR2B | c.460C>T p.L154= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- QARS1 | c.2169G>T p.V723= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- REEP1 | c.510C>A p.P170= | Silent (SNP) | VAF 49/407 reads (12%) | called by muse, mutect2, varscan2
- SEMA5B | c.2409C>T p.R803= | Silent (SNP) | VAF 38/246 reads (15%) | called by muse, mutect2, varscan2
- SETD1B | c.4851C>A p.A1617= | Silent (SNP) | VAF 36/284 reads (13%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.1326G>T p.L442= (on ENST00000308713 / NM_001114099.3; = p.L372= on NM_012410.4) | Silent (SNP) | VAF 65/225 reads (29%) | called by muse, mutect2, varscan2
- SH2D5 | c.700C>T p.L234= (on ENST00000444387 / NM_001103161.2; = p.L150= on NM_001103160.2) | Silent (SNP) | VAF 32/372 reads (9%) | called by muse, mutect2
- SH3TC2 | c.2676G>A p.Q892= | Silent (SNP) | VAF 58/476 reads (12%) | called by muse, mutect2, varscan2
- SLC12A9 | c.1482G>A p.A494= | Silent (SNP) | VAF 31/230 reads (13%) | catalogued as rs772006582, COSV51933225; called by muse, mutect2, varscan2
- SNX31 | c.60C>T p.R20= | Silent (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- SOX1 | c.747C>T p.Y249= | Silent (SNP) | VAF 35/326 reads (11%) | catalogued as rs754283770; called by muse, mutect2, varscan2
- STAG3 | c.3420C>T p.P1140= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as rs370467752, COSV57927689; called by muse, mutect2, varscan2
- SYBU | c.1374T>C p.L458= (on ENST00000276646 / NM_001099754.2; = p.L457= on NM_017786.6) | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- TBX3 | c.1698G>A p.A566= (on ENST00000257566 / NM_016569.4; = p.A546= on NM_005996.4) | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs760080442; called by muse, mutect2, varscan2
- TFDP1 | c.402C>T p.S134= | Silent (SNP) | VAF 21/243 reads (9%) | catalogued as rs753040337; called by muse, mutect2
- TMEM168 | c.1626C>T p.I542= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as rs760593835, COSV57180938; called by muse, mutect2, varscan2
- TNFRSF4 | c.321C>T p.C107= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2, varscan2
- TRABD | c.681C>T p.D227= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs776349218; called by muse, mutect2
- TRAF5 | c.732A>G p.S244= | Silent (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- TRMT44 | c.963T>C p.P321= | Silent (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- TTN | c.52731T>C p.N17577= (on ENST00000591111; = p.N10153= on NM_003319.4) | Silent (SNP) | VAF 92/631 reads (15%) | called by muse, mutect2, varscan2
- USP9X | c.2505T>C p.G835= | Silent (SNP) | VAF 33/147 reads (22%) | called by muse, mutect2, varscan2
- WFIKKN1 | c.1236G>A p.P412= | Silent (SNP) | VAF 23/210 reads (11%) | catalogued as rs368125081; called by muse, mutect2, varscan2
- ZBTB39 | c.1077C>A p.I359= | Silent (SNP) | VAF 36/296 reads (12%) | called by muse, mutect2, varscan2
- ZNF532 | c.3780C>T p.A1260= | Silent (SNP) | VAF 42/463 reads (9%) | catalogued as rs568312860; called by muse, mutect2
- ZNF701 | c.666C>T p.P222= (on ENST00000301093; = p.P156= on NM_018260.3) | Silent (SNP) | VAF 26/230 reads (11%) | catalogued as rs766992238, COSV56526903; called by muse, mutect2, varscan2
- ZNF711 | c.876C>T p.Y292= | Silent (SNP) | VAF 61/459 reads (13%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2388G>A | RNA (SNP) | VAF 17/64 reads (27%) | catalogued as rs1402072888; called by muse, mutect2, varscan2
- AC009093.8 | chr16:29113106 C>T | 5'Flank (SNP) | VAF 21/384 reads (5%) | catalogued as rs780825716; called by muse, mutect2
- ADAD2 | c.559+55G>A | Intron (SNP) | VAF 26/296 reads (9%) | catalogued as rs887616217; called by muse, mutect2
- ADAMTSL4 | chr1:150561163 del T | 3'Flank (DEL) | VAF 10/63 reads (16%) | catalogued as rs1301098882; called by mutect2, pindel, varscan2
- ADGRA1 | chr10:133084814 G>T | 5'Flank (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- AGAP9 | c.*10G>A | 3'UTR (SNP) | VAF 78/918 reads (8%) | catalogued as rs1205630397; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 5/21 reads (24%) | catalogued as rs766264675; called by pindel, varscan2*
- ALG8 | chr11:78100939 G>A | 3'Flank (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- BLNK | c.*14del | 3'UTR (DEL) | VAF 26/236 reads (11%) | catalogued as rs782515286; called by mutect2, varscan2
- C1QTNF3 | c.351+31C>A | Intron (SNP) | VAF 28/259 reads (11%) | called by muse, mutect2, varscan2
- CCDC149 | c.-29C>A | 5'UTR (SNP) | VAF 28/221 reads (13%) | catalogued as rs1208745185; called by muse, mutect2, varscan2
- CCND3 | c.574+10C>A | Intron (SNP) | VAF 54/381 reads (14%) | catalogued as COSV57828619; called by muse, mutect2, varscan2
- CEP41 | c.*320del | 3'UTR (DEL) | VAF 53/300 reads (18%) | catalogued as rs782034329; called by mutect2, varscan2
- CLN3 | c.891-15del | Intron (DEL) | VAF 61/405 reads (15%) | catalogued as rs769259414; called by mutect2, pindel, varscan2
- COL6A1 | c.738+13C>A | Intron (SNP) | VAF 62/485 reads (13%) | called by muse, mutect2, varscan2
- CRTC1 | c.*23G>A | 3'UTR (SNP) | VAF 50/352 reads (14%) | catalogued as rs776798502, COSV58716159; called by muse, mutect2
- CYBC1 | c.127+14del | Intron (DEL) | VAF 34/242 reads (14%) | catalogued as rs755027314; called by mutect2, pindel
- DNAH8 | c.-41-4556A>T | Intron (SNP) | VAF 13/96 reads (14%) | called by muse, varscan2
- ERO1A | c.676+18G>T | Intron (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- FLT4 | c.2648-125C>T | Intron (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- GANC | c.*2213del | 3'UTR (DEL) | VAF 21/108 reads (19%) | catalogued as rs1248831806; called by mutect2, pindel, varscan2
- GLT1D1 | c.413-16del | Intron (DEL) | VAF 24/206 reads (12%) | called by mutect2, pindel
- HP | c.6-89T>C | Intron (SNP) | VAF 58/425 reads (14%) | called by muse, mutect2, varscan2
- IFRD1 | chr7:112475555 del T | 3'Flank (DEL) | VAF 25/140 reads (18%) | catalogued as rs763386499; called by mutect2, varscan2
- IL10RA | c.368-18del | Intron (DEL) | VAF 40/267 reads (15%) | catalogued as rs751713159; called by mutect2, pindel, varscan2
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 35/243 reads (14%) | catalogued as rs764079139; called by mutect2, pindel, varscan2
- KIF23 | c.564-21A>T | Intron (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- KRT6C | c.1203+40del | Intron (DEL) | VAF 69/551 reads (13%) | called by mutect2, pindel, varscan2
- LHFPL5 | c.*10A>G | 3'UTR (SNP) | VAF 51/416 reads (12%) | called by muse, mutect2, varscan2
- MAP7D2 | c.595+1976C>T | Intron (SNP) | VAF 20/192 reads (10%) | catalogued as rs746205641; called by muse, mutect2, varscan2
- MIR20A | chr13:91350858 G>A | 5'Flank (SNP) | VAF 39/187 reads (21%) | catalogued as rs1256577495; called by muse, mutect2, varscan2
- MUCL3 | c.946+852G>A | Intron (SNP) | VAF 127/548 reads (23%) | catalogued as rs920805287; called by muse, mutect2, varscan2
- NAP1L1 | c.1089+40A>G | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- NT5C2 | c.539+212G>A | Intron (SNP) | VAF 21/241 reads (9%) | catalogued as rs918682407; called by muse, mutect2
- NUBP2 | c.17-745del | Intron (DEL) | VAF 50/384 reads (13%) | called by mutect2, pindel, varscan2
- PDGFA | c.580+169G>A | Intron (SNP) | VAF 35/132 reads (27%) | catalogued as rs779027944; called by muse, mutect2, varscan2
- POR | c.237+82G>A | Intron (SNP) | VAF 32/294 reads (11%) | catalogued as rs994090599; called by muse, mutect2, varscan2
- PUS1 | c.74+49C>A | Intron (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- QSER1 | c.5067+29del | Intron (DEL) | VAF 10/82 reads (12%) | catalogued as rs747734792; called by mutect2, varscan2
- RER1 | c.366-89C>T | Intron (SNP) | VAF 35/215 reads (16%) | catalogued as rs550679606; called by muse, mutect2, varscan2
- RUSF1 | c.1016+198A>G | Intron (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- SATB1 | c.1779+619T>C | Intron (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- SH3TC2 | c.280-1326del | Intron (DEL) | VAF 20/83 reads (24%) | catalogued as rs752479043; called by mutect2, varscan2
- SMG1P2 | n.81-3032C>T | Intron (SNP) | VAF 29/141 reads (21%) | catalogued as rs990016329; called by muse, mutect2, varscan2
- SRPK1 | c.13+31G>T | Intron (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- SUGCT | c.1089+2676G>T | Intron (SNP) | VAF 62/253 reads (25%) | catalogued as COSV59311008; called by muse, mutect2, varscan2
- TBC1D3P1 | n.612G>T | RNA (SNP) | VAF 45/523 reads (9%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1143C>T | Intron (SNP) | VAF 47/366 reads (13%) | catalogued as rs1381918059; called by muse, mutect2, varscan2
- USP32 | c.1239+4518del | Intron (DEL) | VAF 12/127 reads (9%) | catalogued as rs772637225; called by mutect2, pindel
- VPS33B | c.-22del | 5'UTR (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- WDR61 | c.12+256del | Intron (DEL) | VAF 5/46 reads (11%) | catalogued as rs754904373, COSV51216526, COSV51217821; called by pindel, varscan2
- ZBTB7C | c.-51C>T | 5'UTR (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- ZFAT | c.-22del | 5'UTR (DEL) | VAF 20/134 reads (15%) | catalogued as rs746459398; called by mutect2, varscan2
- ZNF211 | c.218-650del | Intron (DEL) | VAF 19/148 reads (13%) | called by pindel, varscan2
